TCGA case TCGA-CS-4943 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Thomas Jefferson University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/952dfd5d-e65a-4307-b6a9-2ed2b0d2d9ce

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 37 years; Vital status: Dead; Days to death: 1,106 days (3.0 years).

Diagnoses (1)
1. Astrocytoma, anaplastic: ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 37.1 years (13,565 days); Year of diagnosis: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,106 days (3.0 years); First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 408 days (1.1 years); Treatment outcome: Treatment Ongoing; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 9 (preoperative): Karnofsky performance status: 50; ECOG performance status: 4.
- Days to follow up: 481 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 552 days (1.5 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 1,106.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Seizure.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CS-4943-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.5; Shortest dimension: 0.1.
  Slide TCGA-CS-4943-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-CS-4943-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-CS-4943-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CS-4943-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; History seizures: Yes; History headaches: Yes; First symptom longest duration: > 181 Days; History neoadjuvant medication: Yes; Idh1 mutation test indicator: No; Days from index date to performance status: 9.
- Drug treatment: Pharmaceutical therapy drug name: Temodar.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form 1: New tumor event diagnosis indicator: No; Tumor status: With tumor; Days from index date to performance status: 9.
- Follow-up form 2: Lost to follow-up: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,106 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,106 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,106 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CS-4943-01A-01D-1466-01): tumor purity 0.83, ploidy 3.9, whole-genome doublings 1.
